Somatic mutation profile of tumor specimen C3L-00102-01 (aliquot CPT0001730005_1) from CPTAC case C3L-00102, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 42.8 years (15,616 days).
Specimen C3L-00102-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74a3c721-3e19-4cf1-938f-0319bc2b00fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00102-31 (Blood Derived Normal), aliquot CPT0003940002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05e9fc12-39cb-4876-b8d9-5d2f66f8b288

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Splice Site 3, 5'UTR 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 54/518 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.783-1G>T p.X261_splice | Splice Site (SNP) | VAF 109/1136 reads (10%) | hotspot (GDC flag); catalogued as rs1555525367, CS137625, COSV52668714, COSV52729930, COSV53769335; ClinVar: likely pathogenic / not provided; called by muse, mutect2
- ABCG4 | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 22/440 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs759324902, COSV56644177; called by muse, mutect2
- CFAP299 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 19/310 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs200295695; called by muse, mutect2
- DNAH5 | c.9287G>A p.R3096Q | Missense Mutation (SNP) | VAF 36/592 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1388732051, COSV54203252; ClinVar: uncertain significance; called by muse, mutect2
- FRAS1 | c.8516G>A p.R2839Q | Missense Mutation (SNP) | VAF 66/874 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs752028327, COSV53587372; called by muse, mutect2
- GFER | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 60/1234 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV50191671; called by muse, mutect2
- LTF | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 25/348 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs142920270; called by muse, mutect2
- PKD1L2 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs372674125; called by muse, mutect2
- RUVBL1 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 36/524 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV100494226; called by muse, mutect2
- USP32 | c.3980C>T p.P1327L | Missense Mutation (SNP) | VAF 74/681 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs761651563; called by muse, mutect2, varscan2
- ATAD5 | c.4258+1G>A p.X1420_splice | Splice Site (SNP) | VAF 18/288 reads (6%) | called by muse, mutect2
- CDKN2A | c.189_194del p.L64_L65del | In Frame Del (DEL) | VAF 80/802 reads (10%) | called by mutect2, pindel
- CTDSPL2 | c.586A>C p.N196H | Missense Mutation (SNP) | VAF 50/441 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FUCA1 | c.768+2T>C p.X256_splice | Splice Site (SNP) | VAF 55/449 reads (12%) | called by muse, mutect2, varscan2
- ITPA | c.125-6G>C | Splice Region (SNP) | VAF 103/1076 reads (10%) | called by muse, mutect2
- PDE3A | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2
- SYNCRIP | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 21/365 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0.122); called by muse, mutect2
- TRIM23 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 53/522 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.658); called by muse, mutect2
- ADAMTS4 | c.453C>T p.G151= | Silent (SNP) | VAF 51/447 reads (11%) | catalogued as rs749913480; called by muse, mutect2, varscan2
- CACNA1H | c.2541C>T p.C847= | Silent (SNP) | VAF 30/266 reads (11%) | catalogued as rs201227047, COSV61984094; called by muse, mutect2, varscan2
- FAT4 | c.13635G>A p.P4545= | Silent (SNP) | VAF 58/566 reads (10%) | catalogued as rs757657669, COSV58671354, COSV58695437; called by muse, mutect2, varscan2
- SH3PXD2B | c.1674C>T p.G558= | Silent (SNP) | VAF 22/391 reads (6%) | catalogued as rs761047260; called by muse, mutect2
- SZRD1 | c.309G>T p.L103= | Silent (SNP) | VAF 50/441 reads (11%) | called by muse, mutect2, varscan2
- DOCK2 | c.-27G>A | 5'UTR (SNP) | VAF 5/73 reads (7%) | catalogued as rs927225316; called by muse, mutect2
